CCDI case PBBZHJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ee2bb18e-daae-45c2-922d-9c8c778c661f

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,016 days).

Biospecimens (2 samples)
- Sample 0DLHOM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHP3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
